Somatic mutation profile of tumor specimen TCGA-14-0781-01B (aliquot TCGA-14-0781-01B-01D-1696-08) from TCGA case TCGA-14-0781, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.0 years (17,903 days).
Specimen TCGA-14-0781-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 734f8554-50e9-466c-880b-ee2aa83931b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0781-10A (Blood Derived Normal), aliquot TCGA-14-0781-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf45355c-a557-4f8b-8fdd-dadc157d4bb9

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 3, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM110142, COSV64288690, COSV64296946; called by muse, mutect2, varscan2
- ACTRT1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs996690769, COSV64418926; called by muse, mutect2, varscan2
- AL592490.1 | c.2020G>C p.V674L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV69424507; called by muse, mutect2, varscan2
- ASPM | c.7015A>C p.T2339P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54124639; called by muse, mutect2, varscan2
- CADPS2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1465277551, COSV57349432; called by mutect2, varscan2
- DMGDH | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV54860475; called by muse, mutect2, varscan2
- EPHB4 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 74/888 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); catalogued as COSV62267899; called by muse, mutect2
- FREM1 | c.1985C>G p.T662S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs376703044; called by muse, mutect2, varscan2
- GATA1 | c.389C>A p.T130N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64961468; called by muse, mutect2, varscan2
- GPR65 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV50862347; called by muse, mutect2, varscan2
- HCN1 | c.2455G>A p.V819M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1197215604, COSV57493912; called by muse, mutect2, varscan2
- IGF1R | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV51270058; called by muse, mutect2, varscan2
- KCNA1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66836552; called by muse, mutect2
- LAMA1 | c.3569C>T p.T1190M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1473438503, COSV67532087; called by muse, mutect2, varscan2
- LRFN5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs1486862715, COSV53243274; called by mutect2, varscan2
- MED13 | c.1032G>C p.K344N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.903); catalogued as COSV67261914; called by muse, varscan2
- NAALADL1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs138766443; called by muse, mutect2, varscan2
- PARVB | c.711C>T p.F237= | Splice Region (SNP) | VAF 25/173 reads (14%) | catalogued as rs149571024; called by muse, mutect2, varscan2
- PCLO | c.9965C>A p.P3322H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754889252, COSV61616093; called by muse, mutect2
- PHACTR2 | c.1076T>C p.V359A | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV59850222; called by muse, mutect2, varscan2
- SLC22A10 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs987472951, COSV100235929, COSV60420016; called by muse, mutect2, varscan2
- C2CD6 | c.195del p.N65Kfs*12 | Frame Shift Del (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- CARD6 | c.2445del p.F815Lfs*21 | Frame Shift Del (DEL) | VAF 68/612 reads (11%) | called by mutect2, pindel, varscan2
- GCNT2 | c.41_42del p.L14Hfs*13 | Frame Shift Del (DEL) | VAF 18/167 reads (11%) | called by mutect2, pindel, varscan2
- CFAP54 | c.6195C>T p.D2065= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV61570552; called by muse, mutect2
- KDM8 | c.630C>T p.G210= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV53728333; called by muse, mutect2
- LRRK1 | c.4110C>T p.I1370= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs773680878, COSV52601806; called by muse, mutect2, varscan2
- PFKL | c.519C>T p.D173= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV62462596; called by muse, mutect2
